Somatic mutation profile of tumor specimen TCGA-X6-A8C2-01A (aliquot TCGA-X6-A8C2-01A-11D-A36J-09) from TCGA case TCGA-X6-A8C2, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 56.1 years (20,507 days).
Specimen TCGA-X6-A8C2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c994e3c8-ea57-495e-87a4-e010dd99b319.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X6-A8C2-10A (Blood Derived Normal), aliquot TCGA-X6-A8C2-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bca7ca4-d6a4-4277-912d-2b98900d2fc1

The open-access MAF lists 73 somatic variants for this specimen: 59 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 13, Frame Shift Del 8, Nonsense Mutation 3, Splice Site 2, Nonstop Mutation 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM4 | c.1679C>A p.P560Q | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101257063; called by muse, mutect2, varscan2
- ACTR5 | c.732G>C p.E244D | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99709929, COSV99710152; called by muse, mutect2, varscan2
- APOB | c.2328C>A p.Y776* | Nonsense Mutation (SNP) | VAF 22/67 reads (33%) | catalogued as COSV51949760, COSV99264207; called by muse, mutect2, varscan2
- ARHGEF4 | c.2071T>C p.*691Rext*91 | Nonstop Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as COSV100387709; called by muse, mutect2, varscan2
- ARPP19 | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.807); catalogued as COSV99992876; called by muse, mutect2, varscan2
- ASPDH | c.716G>A p.S239N (on ENST00000389208 / NM_001114598.2; = p.S134N on NM_001024656.3) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV100975863; called by muse, mutect2, varscan2
- BFAR | c.1259A>G p.N420S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.76); catalogued as COSV99902070; called by muse, mutect2, varscan2
- CD300LG | c.455C>A p.A152D | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV99517286; called by muse, mutect2, varscan2
- CDCP2 | c.158A>C p.N53T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV100313368; called by muse, mutect2, varscan2
- CDH1 | c.1345C>A p.Q449K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.078); catalogued as COSV55735077, COSV99931434; called by muse, mutect2, varscan2
- CDH12 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT tolerated (0.87); PolyPhen benign (0.011); catalogued as rs754245616, COSV66386118, COSV66436398; called by muse, mutect2, varscan2
- CKAP2 | c.1625T>C p.V542A (on ENST00000378037 / NM_001098525.2; = p.V541A on NM_018204.5) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as COSV99318121; called by muse, mutect2, varscan2
- COL6A6 | c.431A>T p.E144V | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs759033342, COSV100649965; called by muse, mutect2, varscan2
- CP | c.442A>T p.K148* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as COSV99223819; called by muse, mutect2, varscan2
- CWC22 | c.1066G>A p.G356S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.637); catalogued as COSV99844059; called by muse, mutect2, varscan2
- FAM217A | c.149A>G p.K50R | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99212690; called by muse, mutect2
- FASN | c.4428C>G p.N1476K | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.114); catalogued as COSV100147480; called by muse, mutect2, varscan2
- FOXD3 | c.714G>C p.K238N | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100942806; called by muse, mutect2, varscan2
- FRMD4B | c.2714G>T p.R905L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101273356; called by muse, mutect2, varscan2
- GBP7 | c.564G>T p.K188N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV99642927; called by muse, mutect2, varscan2
- GCOM1 | c.508G>C p.D170H | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as COSV99984692; called by muse, mutect2
- IFNA1 | c.451A>T p.T151S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV99439841; called by muse, mutect2
- IGFN1 | c.2695G>A p.V899M (on ENST00000295591 / NM_001367841.1; = p.V3356M on NM_001164586.2) | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as rs375687736; called by muse, mutect2, varscan2
- KCNA6 | c.643T>A p.S215T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99768426; called by muse, varscan2
- KCNA6 | c.683A>T p.E228V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV99768429; called by muse, varscan2
- LGALS7B | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.858); catalogued as rs771820960, COSV59251947; called by muse, mutect2, varscan2
- MAN2A2 | c.2791A>G p.I931V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.384); catalogued as COSV100847782; called by muse, mutect2, varscan2
- MGA | c.1864C>G p.L622V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV99578900; called by muse, mutect2, varscan2
- MYO1H | c.1150A>G p.N384D | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.248); catalogued as COSV100183221; called by muse, mutect2, varscan2
- NDUFA9 | c.411-2A>G p.X137_splice | Splice Site (SNP) | VAF 18/72 reads (25%) | catalogued as COSV99865363; called by muse, mutect2, varscan2
- NOTCH3 | c.6899T>A p.L2300H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); catalogued as COSV99656254; called by muse, mutect2, varscan2
- NRG3 | c.2113C>A p.Q705K (on ENST00000404547 / NM_001370084.1; = p.Q681K on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.038); catalogued as COSV100930899; called by muse, mutect2, varscan2
- OR2V2 | c.705G>A p.W235* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as rs1185408567, COSV100080033; called by muse, mutect2, varscan2
- PAPOLG | c.454T>A p.F152I | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV99474506; called by muse, mutect2, varscan2
- PCSK5 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100949644; called by muse, mutect2, varscan2
- PLEKHA2 | c.154G>C p.G52R | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101173357; called by muse, mutect2, varscan2
- PPFIA2 | c.869G>T p.R290L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100332399, COSV61054172; called by muse, mutect2, varscan2
- PPRC1 | c.3031G>T p.V1011F | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.233); catalogued as COSV99531402; called by muse, mutect2, varscan2
- SCNN1G | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55600097; called by muse, mutect2
- SFMBT2 | c.1246G>T p.A416S | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as COSV100738574; called by muse, mutect2, varscan2
- SNX29 | c.2003G>A p.R668Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.968); catalogued as rs768619037, COSV100029871, COSV60051903; called by muse, mutect2, varscan2
- SREBF1 | c.2276C>A p.A759D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs529689353, COSV55419487, COSV99888482; called by muse, mutect2, varscan2
- TMEM200A | c.713G>C p.S238T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV51661225, COSV99758550, COSV99758827; called by mutect2, varscan2
- UBE2J1 | c.552C>A p.S184R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs909679519, COSV101470235, COSV101470288; called by muse, mutect2, varscan2
- UNKL | c.118T>C p.S40P | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as rs202202852, COSV100061279; called by muse, mutect2, varscan2
- YTHDC2 | c.1040C>A p.S347Y | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99363013; called by muse, mutect2, varscan2
- ZBED9 | c.295C>A p.Q99K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV101509157; called by muse, mutect2, varscan2
- ZFP37 | c.655A>G p.T219A | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV65286367; called by muse, mutect2, varscan2
- ZNF521 | c.1225T>A p.Y409N | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100831580; called by muse, mutect2, varscan2
- AKAP11 | c.3110del p.K1037Rfs*9 | Frame Shift Del (DEL) | VAF 13/69 reads (19%) | called by mutect2, pindel, varscan2
- SLC12A9 | c.1512_1523del p.S505_L508del | In Frame Del (DEL) | VAF 20/36 reads (56%) | called by mutect2, varscan2
- SLC22A13 | c.1347-1_1351del p.X449_splice | Splice Site (DEL) | VAF 4/21 reads (19%) | called by mutect2, pindel
- SLC2A7 | c.1021del p.V342Wfs*24 | Frame Shift Del (DEL) | VAF 21/103 reads (20%) | called by mutect2, pindel, varscan2
- SLC8A3 | c.983del p.P328Qfs*5 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- SPEF2 | c.1957_1958del p.E653Rfs*2 | Frame Shift Del (DEL) | VAF 15/121 reads (12%) | called by mutect2, varscan2
- STX7 | c.709del p.T237Pfs*23 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- TP53 | c.801_804delinsATA p.N268* | Frame Shift Del (DEL) | VAF 19/22 reads (86%) | called by pindel, varscan2*
- TSHZ2 | c.2536_2543del p.S846Efs*28 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- ZEB2 | c.1039_1040del p.N347Yfs*8 | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | called by mutect2, pindel, varscan2
- CACNA1D | c.1065T>C p.L355= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV55450846; called by muse, mutect2, varscan2
- CD84 | c.25T>C p.L9= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100245853; called by muse, mutect2, varscan2
- CDCA2 | c.846G>A p.V282= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs1156474411, COSV100398778; called by muse, mutect2
- CDH6 | c.1827G>T p.T609= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99418323; called by mutect2, varscan2
- MYBPC2 | c.1206G>A p.K402= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs1282355799, COSV100731662; called by muse, mutect2, varscan2
- MYCBPAP | c.369C>T p.P123= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs762890122, COSV100087833; called by muse, mutect2, varscan2
- OBSCN | c.21687G>A p.R7229= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100802019; called by muse, mutect2, varscan2
- RERE | c.3768G>T p.L1256= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as COSV61945364; called by muse, mutect2
- SLC2A4 | c.576G>A p.L192= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99142665; called by muse, mutect2, varscan2
- SLURP1 | c.99C>A p.T33= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99872838; called by mutect2, varscan2
- SYT9 | c.786C>A p.I262= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs1224791658, COSV59615545; called by muse, mutect2, varscan2
- TERT | c.1449C>T p.N483= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs761174773, COSV57205904, COSV57233607; ClinVar: likely benign; called by muse, mutect2, varscan2
- USH2A | c.7944C>A p.T2648= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100230816; called by muse, mutect2, varscan2
- CCDC144NL | n.539C>T | RNA (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100018876; called by muse, mutect2
